Somatic mutation profile of tumor specimen TCGA-29-1761-01A (aliquot TCGA-29-1761-01A-01W-0633-09) from TCGA case TCGA-29-1761, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.3 years (29,337 days).
Specimen TCGA-29-1761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66c4436a-70e8-44cd-b696-58612dec544a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1761-10A (Blood Derived Normal), aliquot TCGA-29-1761-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6e942b9-2587-4899-89cb-5970fe590fee

The open-access MAF lists 220 somatic variants for this specimen: 163 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 53, Frame Shift Del 8, Splice Site 4, Frame Shift Ins 4, Nonsense Mutation 4, Intron 2, In Frame Del 1, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55932722; called by muse, mutect2, varscan2
- ACOX3 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62711047; called by muse, mutect2, varscan2
- ACTN2 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV63972613; called by muse, mutect2, varscan2
- ADGRF5 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.395); catalogued as rs1409709152, COSV99344713; called by muse, mutect2
- ADGRV1 | c.6863T>C p.V2288A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV67979620; called by muse, mutect2, varscan2
- AEBP1 | c.2920G>A p.G974R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs771934431, COSV56255855; called by muse, mutect2, varscan2
- AFF4 | c.1275G>C p.R425S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.991); catalogued as COSV99534677; called by muse, mutect2, varscan2
- AGBL1 | c.1337G>T p.S446I | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV66850597; called by muse, mutect2, varscan2
- AL035461.3 | c.3013C>T p.Q1005* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV66644588; called by muse, mutect2, varscan2
- ALPK2 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV64490719; called by muse, mutect2, varscan2
- AMBP | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs535072502, COSV54322327, COSV54322517, COSV54325612; called by muse, mutect2, varscan2
- ANK1 | c.47T>A p.F16Y | Missense Mutation (SNP) | VAF 105/838 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV55874948; called by muse, mutect2, varscan2
- ANKRD35 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV62909704; called by muse, mutect2, varscan2
- AP4B1 | c.1496T>C p.L499S | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56723629; called by muse, mutect2, varscan2
- APBB1IP | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV66130818; called by muse, mutect2, varscan2
- APOBEC1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57550175, COSV99981018; called by muse, mutect2
- ASXL3 | c.3306C>G p.I1102M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52459055, COSV99324379; called by muse, mutect2, varscan2
- ATP8A2 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.121); catalogued as COSV99680549; called by muse, mutect2
- AVPR1B | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as rs200893536, COSV65637773; called by muse, mutect2, varscan2
- C20orf194 | c.1468+1G>T p.X490_splice | Splice Site (SNP) | VAF 14/127 reads (11%) | catalogued as COSV52692324; called by muse, mutect2, varscan2
- C2orf78 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101280922; called by muse, mutect2, varscan2
- C2orf78 | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV101280923; called by muse, mutect2, varscan2
- C6 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV99666660; called by muse, mutect2
- CACNA1G | c.6943C>G p.P2315A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs768911008, COSV61720989; called by muse, mutect2, varscan2
- CAPZA3 | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99855960; called by muse, mutect2
- CASP5 | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99507266; called by muse, mutect2
- CD93 | c.1675C>A p.Q559K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55663718; called by muse, mutect2, varscan2
- CDC20 | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV60521772; called by muse, mutect2, varscan2
- CFH | c.3288G>T p.W1096C | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272708823, COSV66406305; called by muse, mutect2, varscan2
- COL5A3 | c.5171C>A p.A1724D | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV99318345; called by muse, mutect2
- COL5A3 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53407106; called by mutect2, varscan2
- COL6A5 | c.6946T>C p.S2316P (on ENST00000312481; = p.S2312P on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV99592188; called by muse, mutect2
- CSE1L | c.1843A>C p.N615H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521879; called by muse, mutect2
- DEFB129 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs1454799016, COSV55731043, COSV99857470; called by muse, mutect2, varscan2
- DERL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV52364104; called by muse, mutect2, varscan2
- DNAH5 | c.8323C>G p.Q2775E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV99446114; called by muse, mutect2
- DNM1L | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99845837; called by muse, mutect2
- DPY19L4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs773985243, COSV68962345; called by muse, mutect2, varscan2
- DSC1 | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.205); catalogued as COSV57142551; called by muse, mutect2, varscan2
- DSN1 | c.569A>T p.K190I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65518627; called by muse, mutect2, varscan2
- EDNRB | c.1243G>A p.V415I (on ENST00000377211 / NM_001201397.1; = p.V325I on NM_000115.5) | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs201437745, COSV57519503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHD3 | c.1393G>C p.A465P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV100434873, COSV59029427; called by muse, mutect2, varscan2
- ELOC | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV53022712; called by muse, mutect2, varscan2
- ENOX2 | c.704del p.R235Nfs*25 (on ENST00000338144 / NM_001382520.1; = p.R206Nfs*25 on NM_006375.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 59/129 reads (46%) | catalogued as COSV57648164; called by mutect2, pindel, varscan2
- ETS1 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.291); catalogued as COSV60092081; called by muse, mutect2, varscan2
- F5 | c.1655A>T p.D552V | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63121359; called by muse, mutect2, varscan2
- F8 | c.5221G>A p.A1741T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs782710956, COSV64270174; called by muse, mutect2, varscan2
- FANCA | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV66880712; called by muse, mutect2, varscan2
- FER1L6 | c.1676A>G p.K559R | Missense Mutation (SNP) | VAF 34/602 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV101205539; called by muse, mutect2
- FLG2 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 90/839 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as rs572992221, COSV66167011; called by muse, mutect2
- FSIP2 | c.17299A>G p.K5767E | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV58079748; called by muse, mutect2, varscan2
- GBX2 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60444947; called by muse, mutect2, varscan2
- GCNT4 | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280531; called by muse, mutect2, varscan2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 12/128 reads (9%) | catalogued as rs763284415; called by mutect2, pindel
- GLT8D2 | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62561208; called by muse, mutect2, varscan2
- GNAL | c.310G>T p.V104F (on ENST00000269162 / NM_001142339.3; = p.V181F on NM_182978.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV52324031; called by muse, mutect2, varscan2
- GOLGB1 | c.6689A>C p.E2230A | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV61462373; called by muse, mutect2, varscan2
- GPR155 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV55037721; called by muse, mutect2, varscan2
- GPR180 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1566975812, COSV100979007; called by muse, mutect2
- H2AC14 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100297515; called by muse, mutect2
- HEPHL1 | c.552G>C p.W184C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59889878; called by muse, mutect2, varscan2
- IFIH1 | c.970A>T p.N324Y | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124960; called by muse, mutect2, varscan2
- IGKV2-28 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs1187705131; called by muse, mutect2, varscan2
- ILDR2 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV54829144; called by muse, mutect2, varscan2
- INSIG2 | c.370-1G>T p.X124_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV55521997; called by muse, mutect2, varscan2
- INTS3 | c.2865A>C p.Q955H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV99669756; called by muse, mutect2, varscan2
- KANSL1 | c.1319C>G p.A440G | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV52265652; called by muse, mutect2, varscan2
- KANSL2 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63479464; called by muse, varscan2
- KCNK2 | c.476-1G>T p.X159_splice (on ENST00000444842 / NM_001017425.3; = p.X144_splice on NM_014217.4) | Splice Site (SNP) | VAF 20/185 reads (11%) | catalogued as COSV67203732; called by muse, mutect2, varscan2
- KIAA0100 | c.4981C>T p.R1661W | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs756616026, COSV66490937; called by muse, mutect2
- KMT2C | c.7425G>A p.M2475I | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100068596, COSV51497770; called by muse, mutect2
- KMT2E | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.243); catalogued as COSV99995929; called by muse, mutect2
- KNTC1 | c.1721A>T p.N574I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100338013; called by muse, mutect2
- LAMP1 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as COSV100208521; called by muse, mutect2
- LLGL2 | c.151_157del p.T51Lfs*24 | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | catalogued as COSV51343006; called by mutect2, varscan2
- LRBA | c.8578C>G p.Q2860E | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63950785; called by muse, mutect2, varscan2
- LRP2BP | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV60749371, COSV60750863; called by muse, mutect2, varscan2
- LRRN3 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57817858; called by muse, mutect2, varscan2
- MAP4K1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV67708852; called by muse, varscan2
- MAP7 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643778; called by muse, mutect2
- MATN3 | c.245T>G p.L82W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68099455; called by muse, mutect2, varscan2
- MCHR2 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99911627; called by muse, mutect2
- MKS1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs201237547, COSV58302832; called by muse, varscan2
- MRGPRX2 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61673840, COSV61674849; called by muse, mutect2, varscan2
- MYH1 | c.1008+1G>A p.X336_splice | Splice Site (SNP) | VAF 53/205 reads (26%) | catalogued as COSV56844544; called by muse, mutect2, varscan2
- NAPG | c.218A>T p.H73L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100529676; called by muse, mutect2
- NEGR1 | c.776A>T p.K259I | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60832684; called by muse, mutect2, varscan2
- NFKB1 | c.329C>T p.A110V (on ENST00000394820 / NM_001382627.1; = p.A111V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56954860; called by muse, mutect2, varscan2
- NOVA1 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV57473182; called by muse, mutect2, varscan2
- NUDT10 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 34/778 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726789; called by muse, mutect2
- OR51I2 | c.76T>G p.W26G | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100413323, COSV58299592; called by muse, mutect2, varscan2
- OR5B2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.114); catalogued as rs778753916, COSV56907681; called by muse, mutect2, varscan2
- ORC1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1313419907, COSV65363400; called by muse, mutect2, varscan2
- PAN2 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV99228146; called by muse, mutect2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2
- PDZRN4 | c.2143G>C p.D715H (on ENST00000402685 / NM_001164595.2; = p.D457H on NM_013377.4) | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100113686, COSV54193857; called by muse, mutect2, varscan2
- PEAK1 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 56/504 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV56931750; called by muse, mutect2, varscan2
- PIK3CB | c.1987A>T p.R663* | Nonsense Mutation (SNP) | VAF 60/873 reads (7%) | catalogued as COSV100005303; called by muse, mutect2
- PLK2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV57106046; called by muse, mutect2, varscan2
- PLOD3 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as rs777497883, COSV56181529; called by muse, mutect2, varscan2
- PLXNA4 | c.1765G>C p.A589P | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV58108670, COSV58168117; called by muse, mutect2, varscan2
- PRDM11 | c.1220A>T p.K407M (on ENST00000530656 / NM_001359633.1; = p.K373M on NM_001256695.1) | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV55438074; called by muse, mutect2, varscan2
- PRDM2 | c.2772T>A p.D924E | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as COSV52443471; called by muse, mutect2, varscan2
- PRDM9 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV57003367; called by muse, mutect2, varscan2
- PTCH1 | c.2515C>G p.Q839E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.115); catalogued as COSV100107795; called by muse, mutect2
- PTPRZ1 | c.636A>T p.L212F | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101099719; called by muse, mutect2
- PUM2 | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57578392; called by muse, mutect2, varscan2
- RAET1G | c.116T>A p.V39D | Missense Mutation (SNP) | VAF 34/515 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100951641; called by muse, mutect2
- RARG | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV58432076; called by muse, mutect2, varscan2
- RASSF2 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | catalogued as rs757887568, COSV65081765; called by muse, mutect2, varscan2
- RIF1 | c.6247A>T p.N2083Y | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as COSV54613261; called by muse, mutect2, varscan2
- RMC1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1386953796, COSV99339924; called by muse, mutect2
- RNF19A | c.2016dup p.S673Ifs*5 | Frame Shift Ins (INS) | VAF 47/417 reads (11%) | catalogued as rs1225721197; called by mutect2, pindel, varscan2
- RYR2 | c.8653G>C p.D2885H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV63667115; called by muse, mutect2, varscan2
- RYR3 | c.837A>T p.R279S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.361); catalogued as COSV66780093; called by muse, mutect2, varscan2
- SAFB2 | c.1094C>G p.P365R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53040937; called by mutect2, varscan2
- SERPINA11 | c.1179C>G p.H393Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV100593959; called by muse, mutect2
- SGMS1 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100693184, COSV62371150; called by muse, mutect2, varscan2
- SLC14A2 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs779856526, COSV54906904; called by muse, mutect2, varscan2
- SLC25A47 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as rs1422942529, COSV59924619; called by muse, mutect2, varscan2
- SLC4A3 | c.3108dup p.L1037Afs*35 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | catalogued as rs757961785; called by mutect2, varscan2
- SMC1A | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV59128063; called by muse, mutect2, varscan2
- SMR3B | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV59228603; called by muse, mutect2, varscan2
- SRFBP1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59581845; called by muse, mutect2, varscan2
- STIP1 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV54177454; called by muse, mutect2, varscan2
- SYNE1 | c.19138G>C p.E6380Q (on ENST00000367255 / NM_182961.4; = p.E6309Q on NM_033071.3) | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.395); catalogued as COSV54921468; called by muse, mutect2, varscan2
- TBX5 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59858827; called by muse, mutect2, varscan2
- TEF | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56747374; called by muse, mutect2, varscan2
- TEKT4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54623307; called by muse, mutect2, varscan2
- TENM1 | c.7085G>C p.G2362A | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64426304; called by muse, mutect2, varscan2
- TLR2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52605282; called by muse, mutect2, varscan2
- TM4SF1 | c.62G>C p.C21S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.076); catalogued as COSV100542955, COSV59524659; called by muse, mutect2, varscan2
- TMEM174 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs375705483; called by muse, mutect2, varscan2
- TNN | c.3613C>T p.H1205Y | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99511293; called by muse, mutect2
- TOPBP1 | c.1162del p.R388Vfs*5 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as COSV53432929; called by mutect2, pindel, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 258/492 reads (52%) | catalogued as rs587780067; called by pindel, varscan2
- TRANK1 | c.6770G>C p.R2257P | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV100085395, COSV57142977; called by muse, mutect2, varscan2
- TRIM51 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV55264354; called by muse, mutect2, varscan2
- TRIM54 | c.904C>G p.P302A (on ENST00000380075 / NM_187841.3; = p.P344A on NM_032546.4) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as COSV99274209; called by muse, mutect2
- TRIML2 | c.1103A>T p.D368V | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV58714857; called by muse, mutect2, varscan2
- TRPC1 | c.1528T>A p.Y510N (on ENST00000476941 / NM_001251845.2; = p.Y476N on NM_003304.4) | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as COSV56423257; called by muse, mutect2, varscan2
- TSNARE1 | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV56171533; called by muse, mutect2, varscan2
- TTC6 | c.1559T>C p.I520T (on ENST00000267368; = p.I1886T on NM_001310135.3) | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57446882; called by muse, mutect2, varscan2
- TTN | c.80173G>A p.V26725I (on ENST00000591111; = p.V19301I on NM_003319.4) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | PolyPhen benign (0.003); catalogued as rs367800789; called by muse, mutect2, varscan2
- TTN | c.45437T>G p.V15146G (on ENST00000591111; = p.V7722G on NM_003319.4) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | PolyPhen benign (0.1); catalogued as COSV59914568; called by muse, mutect2, varscan2
- USHBP1 | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.043); catalogued as COSV99394052; called by muse, mutect2
- USP28 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV50156428; called by muse, mutect2, varscan2
- UTS2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as rs891005798, COSV50013128; called by muse, mutect2, varscan2
- XRCC6 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV63158518; called by muse, mutect2, varscan2
- XYLT2 | c.1742G>C p.C581S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV50016901; called by muse, mutect2, varscan2
- YY1AP1 | c.934C>A p.L312I (on ENST00000295566 / NM_139118.2; = p.L255I on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/690 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99803572; called by muse, mutect2
- ZEB2 | c.572C>G p.A191G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV57952400; called by muse, mutect2, varscan2
- ZNF473 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV54522211; called by muse, mutect2, varscan2
- ZNF610 | c.1337A>G p.H446R | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747644280, COSV58343802; called by muse, mutect2
- ZP2 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV54812426, COSV54815916; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4601T>C p.L1534P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ANKRD20A1 | c.2276A>T p.E759V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- CAMK4 | c.708_715del p.C236* | Frame Shift Del (DEL) | VAF 87/353 reads (25%) | called by mutect2, pindel, varscan2
- CTR9 | c.2767_2770delinsTT p.D923Lfs*3 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | called by pindel, varscan2*
- EEF1A1 | c.285_286del p.H95Qfs*15 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- H2BC3 | c.181_189del p.G61_M63del | In Frame Del (DEL) | VAF 31/284 reads (11%) | called by mutect2, pindel, varscan2
- PROX1 | c.999_1002del p.R334Tfs*18 | Frame Shift Del (DEL) | VAF 34/242 reads (14%) | called by pindel, varscan2
- TMPRSS13 | c.1539dup p.P514Afs*5 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, varscan2
- ADAM28 | c.2172C>A p.P724= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as rs753697548, COSV56098337; called by muse, mutect2, varscan2
- AKAP4 | c.2298T>A p.S766= | Silent (SNP) | VAF 23/568 reads (4%) | catalogued as COSV100654183; called by muse, mutect2
- APOB | c.6654C>T p.I2218= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV51925671; called by muse, mutect2, varscan2
- ATP9B | c.1416C>G p.T472= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs373609399, COSV56963706; called by muse, mutect2
- BFAR | c.93A>G p.E31= | Silent (SNP) | VAF 91/312 reads (29%) | catalogued as COSV55492669; called by muse, mutect2, varscan2
- C9orf43 | c.570C>G p.T190= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV55912006, COSV55912893; called by muse, mutect2, varscan2
- CCDC149 | c.480T>G p.A160= | Silent (SNP) | VAF 50/454 reads (11%) | catalogued as COSV60877024; called by muse, mutect2, varscan2
- CCNB3 | c.3129C>T p.T1043= | Silent (SNP) | VAF 36/975 reads (4%) | catalogued as rs1557214929, COSV99328603; called by muse, mutect2
- CCR10 | c.45T>C p.S15= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1251879898, COSV52848379; called by muse, mutect2, varscan2
- CNGA3 | c.2049C>T p.P683= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs923799882, COSV55622735; called by muse, mutect2, varscan2
- CNTNAP2 | c.340C>A p.R114= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100662536, COSV62150589; called by muse, mutect2, varscan2
- COPA | c.699C>A p.R233= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV54098771; called by muse, mutect2, varscan2
- CPO | c.33G>A p.L11= | Silent (SNP) | VAF 44/296 reads (15%) | catalogued as COSV55938819; called by muse, mutect2, varscan2
- DNAH17 | c.13203G>A p.P4401= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs765424936, COSV53143700; called by muse, mutect2, varscan2
- FAM135B | c.4206C>A p.L1402= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV52736745, COSV52737679; called by muse, mutect2, varscan2
- FAM161A | c.714A>T p.V238= | Silent (SNP) | VAF 56/281 reads (20%) | catalogued as COSV56764552; called by muse, mutect2, varscan2
- FAM83B | c.1845G>A p.Q615= | Silent (SNP) | VAF 13/237 reads (5%) | catalogued as COSV100174139; called by muse, mutect2
- FARP2 | c.1014C>T p.G338= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as COSV99884134; called by muse, mutect2, varscan2
- GJA8 | c.360T>G p.T120= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV53787969; called by muse, mutect2, varscan2
- GPNMB | c.1365A>G p.R455= (on ENST00000381990 / NM_001005340.2; = p.R443= on NM_002510.3) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs779307691, COSV51697143; called by muse, mutect2, varscan2
- GPR32 | c.525G>A p.A175= | Silent (SNP) | VAF 84/145 reads (58%) | catalogued as rs768827782, COSV54513865; called by muse, mutect2, varscan2
- H2AC14 | c.342C>A p.A114= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100297512; called by muse, mutect2
- HEPN1 | c.198C>T p.F66= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV53428921; called by muse, mutect2, varscan2
- HTR1E | c.555C>T p.Y185= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as COSV100540989, COSV104397870; called by muse, mutect2
- HVCN1 | c.429C>T p.S143= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV99657095; called by muse, mutect2
- HYDIN | c.11811G>A p.P3937= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs112468877, COSV66641077, COSV66642263; called by mutect2, varscan2
- IKBKE | c.1272G>A p.Q424= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100898109; called by muse, mutect2
- MARK3 | c.57G>C p.T19= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV53510419; called by muse, mutect2
- MFSD2A | c.636G>A p.A212= (on ENST00000372809 / NM_001136493.3; = p.A199= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs6686999; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP14 | c.1533A>G p.G511= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100313977; called by muse, mutect2
- MMP16 | c.1008C>T p.P336= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs761488939, COSV54153288, COSV54174570, COSV54183762; called by muse, mutect2, varscan2
- NCKAP1 | c.2886A>G p.S962= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs1039299514, COSV62940052; called by muse, mutect2, varscan2
- OR4C16 | c.138T>C p.S46= | Silent (SNP) | VAF 130/266 reads (49%) | catalogued as rs755573792, COSV100113897; called by muse, mutect2
- OR52N1 | c.21C>T p.T7= | Silent (SNP) | VAF 80/283 reads (28%) | catalogued as COSV57693007; called by muse, mutect2, varscan2
- OR5D16 | c.147G>A p.V49= | Silent (SNP) | VAF 52/402 reads (13%) | catalogued as COSV65721405; called by muse, mutect2, varscan2
- PAPPA2 | c.4641C>T p.D1547= | Silent (SNP) | VAF 33/253 reads (13%) | catalogued as rs1480768334, COSV62792028; called by muse, mutect2, varscan2
- POLR2A | c.4710C>G p.G1570= | Silent (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- PRB3 | c.174A>G p.E58= | Silent (SNP) | VAF 86/1268 reads (7%) | catalogued as rs1565763435, COSV99685552; called by muse, mutect2
- PSMA3 | c.15C>G p.G5= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV53616463; called by muse, mutect2, varscan2
- RAB4B | c.408C>T p.A136= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63824437; called by muse, mutect2, varscan2
- RBPJL | c.1146C>T p.V382= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100643451; called by muse, mutect2
- SAMD14 | c.111G>C p.L37= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99557367; called by muse, mutect2, varscan2
- SETX | c.3417A>G p.E1139= | Silent (SNP) | VAF 57/399 reads (14%) | catalogued as COSV56379927; called by muse, mutect2, varscan2
- TANGO6 | c.669C>T p.I223= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs771889838, COSV55761534; called by muse, mutect2, varscan2
- TBC1D32 | c.1263A>G p.G421= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV51537861; called by muse, mutect2, varscan2
- TG | c.597C>T p.T199= | Silent (SNP) | VAF 49/82 reads (60%) | catalogued as COSV55067034; called by muse, mutect2, varscan2
- TRAV18 | c.72C>A p.T24= | Silent (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- TRPM3 | c.2157C>T p.D719= (on ENST00000357533 / NM_001366142.2; = p.D562= on NM_020952.6) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs371313289; called by muse, mutect2, varscan2
- TTN | c.38715C>T p.D12905= (on ENST00000591111; = p.D5481= on NM_003319.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs764977967, COSV59914593; ClinVar: likely benign; called by muse, mutect2, varscan2
- TYK2 | c.2919G>A p.S973= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV53385250; called by muse, varscan2
- UGT2B4 | c.1492C>T p.L498= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as COSV59315577, COSV59315704; called by muse, mutect2, varscan2
- USP35 | c.2472G>T p.L824= | Silent (SNP) | VAF 38/255 reads (15%) | catalogued as COSV60866356; called by muse, mutect2, varscan2
- VWF | c.6855C>T p.S2285= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs745659470, COSV54613263; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822005 A>T | 5'Flank (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- C3P1 | n.2728A>G | RNA (SNP) | VAF 50/386 reads (13%) | catalogued as rs1244523992; called by muse, mutect2, varscan2
- SPTBN1 | c.148+32271A>C | Intron (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61686115; called by muse, mutect2, varscan2
- TTN | c.34265-5263T>A | Intron (SNP) | VAF 69/287 reads (24%) | catalogued as rs989137248, COSV59914620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
